Somatic mutation profile of tumor specimen MP2PRT-PAPVUX-TMP1-A (aliquot MP2PRT-PAPVUX-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPVUX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (860 days).
Specimen MP2PRT-PAPVUX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12db0df6-ea75-418e-a075-d619a33f1a4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPVUX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPVUX-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e1542d5-79cd-4ed8-870e-23113bdd2e25

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL1 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs767212943; called by muse, mutect2, varscan2
- MYMK | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.438); catalogued as rs546271887, COSV60600907, COSV60601851; called by muse, mutect2, varscan2
- TECTA | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs752254649, COSV50701840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDFY3 | c.9349G>A p.V3117I | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs972784154, COSV55693840; called by muse, mutect2, varscan2
- KMT2D | c.16088C>T p.A5363V | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NBPF1 | c.50T>C p.I17T | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SOX10 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 15/442 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL8A1 | c.1998C>T p.H666= | Silent (SNP) | VAF 38/268 reads (14%) | catalogued as rs776879409; called by muse, mutect2, varscan2
- KCNG4 | c.951G>A p.P317= | Silent (SNP) | VAF 51/322 reads (16%) | catalogued as rs770703354, COSV57585342; called by muse, mutect2, varscan2
- ZFP42 | c.132C>T p.S44= | Silent (SNP) | VAF 46/392 reads (12%) | catalogued as rs372412310; called by muse, mutect2, varscan2
